Somatic mutation profile of tumor specimen BA2671D (aliquot aq-BA2671D) from BEATAML1.0 case 2237, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 73.2 years (26,735 days).
Specimen BA2671D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bef86e07-dce6-43d2-a9af-14b5e71dd67f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2029D (Solid Tissue Normal), aliquot aq-BA2029D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c7267cd-e5a0-4b93-a19f-976822d162a4

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 4, Silent 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A4GNT | c.982G>T p.E328* | Nonsense Mutation (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- NIBAN3 | c.1049C>A p.A350E | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.029); called by muse, mutect2
- PWWP3B | c.217C>A p.Q73K | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.049); called by muse, mutect2
- SLC5A4 | c.17G>T p.S6I | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.063); called by muse, mutect2
- WASHC2C | c.122C>A p.A41E | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2
- ALPK3 | c.1725G>A p.G575= | Silent (SNP) | VAF 26/65 reads (40%) | catalogued as rs1465453438; called by muse, mutect2, varscan2
- IGF2R | c.4191G>A p.T1397= | Silent (SNP) | VAF 25/111 reads (23%) | catalogued as rs1362340652; called by muse, mutect2, varscan2
- SLC25A47 | c.312C>A p.A104= | Silent (SNP) | VAF 8/16 reads (50%) | called by muse, varscan2
